FM case AD5429 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/204bb7b0-b82e-4ee2-ae16-faec015624ad

Male, 38.3 years: Carcinoma, NOS (ICD-O-3 8010/3) of the thymus; metastasis biopsied or resected from the mediastinum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
